Somatic mutation profile of tumor specimen ALCH-B2FE-TTP1-A (aliquot ALCH-B2FE-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2FE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.4 years (25,708 days).
Specimen ALCH-B2FE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1835c53-be1c-41dc-91c7-d279e05bbfc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2FE-NB1-A (Blood Derived Normal), aliquot ALCH-B2FE-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37a3f73d-b6d2-4df4-9be8-ab4df2e26205

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 2, RNA 1, In Frame Del 1, Intron 1, 5'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 56/285 reads (20%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | hotspot (GDC flag); catalogued as CS971912, COSV52665806, COSV52762622, COSV52838014; called by muse, mutect2, varscan2
- ABCB4 | c.3643G>T p.E1215* (on ENST00000265723 / NM_018849.3; = p.E1208* on NM_000443.4) | Nonsense Mutation (SNP) | VAF 34/432 reads (8%) | catalogued as COSV55934084; called by muse, mutect2
- COL6A2 | c.1674G>A p.A558= | Splice Region (SNP) | VAF 10/59 reads (17%) | catalogued as rs144334894, COSV100153204; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- F8 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868944893, CM081254; called by muse, mutect2
- FOXRED1 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as rs752413987; called by muse, mutect2
- HMGCS2 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1064797117, COSV65567142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECTIN4 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1478255615, COSV63513046; called by muse, mutect2, varscan2
- PKN1 | c.1495G>T p.G499W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54398311; called by muse, mutect2
- SYNE1 | c.3896C>T p.A1299V (on ENST00000367255 / NM_182961.4; = p.A1306V on NM_033071.3) | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); catalogued as rs1184329555, COSV99553822; called by muse, mutect2
- TENM4 | c.3899G>A p.R1300Q | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs754346137, COSV53613638; called by muse, mutect2
- ZNF804B | c.3182C>A p.P1061H | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV60836925; called by muse, mutect2
- DEFB110 | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR32 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDRG1 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 97/346 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR4D1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- OR51B6 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.972); called by muse, mutect2
- OR52K2 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PABPC3 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- RFK | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.083); called by muse, mutect2
- SEC16B | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLC4A2 | c.1887C>G p.F629L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.132); called by muse, mutect2
- SNX6 | c.187C>T p.H63Y (on ENST00000652385; = p.H51Y on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TRIM40 | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2
- USP24 | c.6833G>T p.C2278F | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2
- XPO7 | c.110T>G p.F37C | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- KANSL1L | c.807C>T p.L269= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- KCTD19 | c.57A>T p.V19= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- PRPF8 | c.4770T>G p.V1590= | Silent (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- RTL5 | c.912T>C p.C304= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- SYNE2 | c.1776G>A p.V592= | Silent (SNP) | VAF 38/418 reads (9%) | called by muse, mutect2
- XRCC3 | c.891G>T p.L297= | Silent (SNP) | VAF 51/176 reads (29%) | called by muse, mutect2, varscan2
- AC016526.1 | chr14:76310878 C>T | 5'Flank (SNP) | VAF 11/195 reads (6%) | called by muse, mutect2
- AL162726.3 | n.255+83163A>G | Intron (SNP) | VAF 24/252 reads (10%) | catalogued as rs1457837343; called by muse, mutect2
- CCDC39 | n.656G>T | RNA (SNP) | VAF 30/232 reads (13%) | called by muse, mutect2, varscan2
